Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4890, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4890-01A (Primary Tumor).

DIAGNOSIS
(A) PERIAORTIC LYMPH NODE:
One lymph node, no tumor present.
(B) LEFT KIDNEY AND ADRENAL:
RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN
NUCLEAR GRADE 4 (14.0 CM).
TUMOR INVADES RENAL PELVIS AND RENAL SINUS ADIPOSE TISSUE.
TUMOR INVADES RENAL VEIN.
Ureter, hllar vascular and soft tissue margins free of tumor.
Adrenal gland free of tumor.
GROSS DESCRIPTION
(A) PERIAORTIC LYMPH NODE- A single lymph node 2.5 x 1.0 x 1.0 em.
The specimen is serially sectioned and entirely submitted in A1-A2.
(B) LEFT KIDNEY AND ADRENAL- A nephrectomy specimen (21.0 x 18.0 x
13.0 em) with attached unremarkable adrenal gland (7.0 x 2.0 x 1.5 em).
A tan-yellow variegated solid tumor mass with focal hemorrhagic and
cystic areas (14.0 x 14.0 x 12.0 em) comprises approximately 80% of the
entire kidney. The tumor grossly involves the renal sinus, renal vein,
and is present in the pelvis. The tumor extends to perinephric fat and
is 0.2 em from the closest soft tissue margin. The ureter, renal vein,
and artery margins are free of tumor. Representative portions of tumor
are submitted to tumor bank and electron microscopy.
INK CODE: Black- closest external surface of tumor.
SECTION CODE: 81, renal vein, artery and ureter margins; 82, tumor
in pelvis/ureter; 83, tumor In renal vein; 84 tumor in renal sinus;
85-86, tumor with closest external surface; 87-815, additional sections
uninvolved kidney; 817, section of adrenal gland.
CLINICAL HISTORY
None given.
SNOMED CODES
T-71000, T-C4600, M-83123
1
TCGA-CJ-4890

Source: NCI Genomic Data Commons file 3c4af72d-caef-4e07-adf0-3b80769b8fcf (TCGA-CJ-4890.CBA5F8ED-E2C0-4472-8695-5260EE594B98.PDF), Data Release 46.0 - August 10, 2026; text from the embedded text layer of the scanned PDF (scanner OCR).